Surgical pathology report (de-identified scan), TCGA case TCGA-24-2297, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2297-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT
FINAL

*** Converted Case * This report may not match the original report format**

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: [REDACTED]

DOB: [REDACTED]

Service: [REDACTED]

Location: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Accession #: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Accessioned: [REDACTED]

Reported: [REDACTED]

Physician(s): [REDACTED]

CGA-24-2297

DIAGNOSIS:

OVARY, RIGHT, SALPINGO-OOPHORECTOMY - PAPILLARY SEROUS
ADENOCARCINOMA (FIGO III)

OVARY, LEFT, SALPINGO-OOPHORECTOMY - PAPILLARY SEROUS
ADENOCARCINOMA (SEE COMMENT)

SOFT TISSUE, OMENTUM, BIOPSY - METASTATIC ADENOCARCINOMA

SOFT TISSUE, RIGHT CUL DE SAC, BIOPSY - METASTATIC ADENOCARCINOMA

SMALL INTESTINE, PROXIMAL, RESECTION - METASTATIC ADENOCARCINOMA
EXTENDING TRANSMURALLY TO
THE MUCOSA
- MARGINS OF RESECTION FREE
OF TUMOR

SMALL INTESTINE, NOT OTHERWISE SPECIFIED, RESECTION
- METASTATIC ADENOCARCINOMA,
EXTENDING TRANSMURALLY TO
THE MUCOSA
- MARGINS OF RESECTION FREE OF TUMOR

LARGE INTESTINE, TRANSVERSE COLON, RESECTION
- METASTATIC ADENOCARCINOMA EXTENDING
TRANSMURALLY TO THE MUCOSA
- TUMOR PRESENT AT RESECTION MARGIN

SOFT TISSUE, MESENTERY, BIOPSY - METASTATIC ADENOCARCINOMA

LYMPH NODE, PERICOLONIC, RESECTION - METASTATIC ADENOCARCINOMA (1
OF 2 NODES)

LARGE INTESTINE, EEA REMNANT, RESECTION
- METASTATIC ADENOCARCINOMA

LARGE INTESTINE, SIGMOID SEROSA, BIOPSY
- METASTATIC ADENOCARCINOMA

SKIN, UMBILICUS, BIOPSY - NO EVIDENCE OF MALIGNANCY

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY
- NO EVIDENCE OF MALIGNANCY

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY
- NO EVIDENCE OF MALIGNANCY

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By Conversion

Intraoperative Consultation:

Ovary, right, right salpingo-oophorectomy

• "Papillary serous carcinoma" by

Microscopic Description and Comment:

Sections from both ovaries show carcinoma, primarily of the papillary serous type. Rare foci of more bland-appearing endometrioid type carcinoma comprise less than 10% of the tumor in the right ovary. Sections from the left ovary show a mixture of papillary serous and endometrioid types. Much greater than 90% of the metastases is represented by carcinoma of the papillary serous type. [REDACTED] has reviewed several slides and concurs with the diagnosis.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. The HISTOLOGIC DIAGNOSIS is:
Serous adenocarcinoma [REDACTED]
2. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Right and left ovary (synchronous primary tumors) [REDACTED]
3. The FIGO GRADE of the tumor is:
III (Tumor composed of greater than 50% solid cellular nests) [REDACTED]
4. The NUCLEAR (BRODEUR'S) GRADE of the tumor is:
G3 (Poorly-differentiated) [REDACTED]
5. Tumor IS identified on the ovarian surface(s). [REDACTED]
6. Tumor DOES invade the mesovarium. [REDACTED]
7. Tumor DOES NOT invade the adjacent fallopian tube. [REDACTED]
8. Tumor DOES invade the pelvic soft tissue. [REDACTED]
9. Tumor involvement of the pelvic peritoneum is PRESENT. [REDACTED]
10. Metastatic involvement of the EXTRAPELVIC peritoneum is PRESENT. [REDACTED]
11. Metastatic involvement of the omentum is PRESENT. [REDACTED]
12. The maximum dimension of tumor implants outside the true pelvis is 2.0 cm. (Enter "0" if no implants.) [REDACTED]
13. Metastatic involvement of the uterine serosa CANNOT BE EVALUATED. [REDACTED]
14. Metastatic involvement of the endometrium CANNOT BE EVALUATED. [REDACTED]
15. Regional lymph node metastases CANNOT BE EVALUATED. [REDACTED]
16. The total number of regional lymph nodes examined is 0. [REDACTED]
17. The total number of metastatically-involved regional lymph nodes is 0 (but 1 of 2 pericolon nodes contains metastatic tumor. [REDACTED])
18. DETAILED STAGING INFORMATION:
Based on the above information, the PRIMARY TUMOR is classified as:
T3b IIIB Macroscopic peritoneal metastasis beyond true pelvis, with no implant greater than 2 cm in maximum dimension (OV 83)
THE REGIONAL LYMPH NODES are classified as:
NX (Nodal status cannot be assessed) [REDACTED]
THE STATUS OF DISTANT TUMOR SITES is classified as:
MX (Status cannot be assessed) [REDACTED]
19. The FINAL AJCC/FIGO STAGE IS:
3b (T3b/ N0/ M0) IIIB [REDACTED]

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

History:

The patient is a [REDACTED] with complaints of abdominal pain. A work-up revealed a large pelvic mass. [REDACTED] is status post total abdominal hysterectomy for prolapse. Clinical diagnosis: Papillary serous carcinoma - metastatic. Operative procedure: Exploratory laparotomy, bowel resection and tumor resection. An intraoperative non-microscopic consultation was obtained and interpreted as: "Ovary, right, salpingo-oophorectomy - 10.5 x 6.5 x 3 cm previously opened cystic mass. Tan-brown papillary tumor approximately 4.5 cm present at prior incision and appears to involve cervix. A second discrete 1.8 cm papillary lesion present on internal surface. Touch prep shows malignant cells. Tissue for [REDACTED] DNA and research taken per [REDACTED]"

Specimen(s) Received:

A: FS1 RIGHT OVARY, BSO
B: X1 RIGHT OVARY, BSO
C: OMENTUM, OMENTAL BIOPSY, OMENTAL BIOPSY
D: LEFT TUBE/OVARY
E: RIGHT CULDESAC BIOPSY
F: PORTION SMALL BOWEL (PROXIMAL)
G: PORTION SMALL BOWEL
H: MESENTERIC TUMOR MASS
I: PORTION TRANSVERSE COLON
J: EEA REMNANT
K: UMBILICUS
L: SIGMOID SEROSA TUMOR TISSUE

Gross Description:

The specimens are received in twelve containers of formalin, each labelled with the patient's name. The first container is additionally labelled "omentum." It contains two irregular sheets of well-vascularized fibrofatty tissue. The first measures 8 x 6 x 2.5 cm and exhibits a shiny, gray-tan, unilocular cyst measuring 2.5 cm in greatest dimension. The cyst wall is focally solid, this area being consistent with metastatic tumor. The second piece of tissue measures 23 x 11 x 1.5 cm in greatest dimension and exhibits a single focus consistent with metastatic tumor. This focus is glistening, tan and solid and measures 1 x 0.5 x 0.4 cm. Labelled A, a cyst wall with solid area consistent with tumor; B, probable tubal nodule in larger piece of tissue. [REDACTED]

The second container is additionally labelled "left tube/ovary," and contains an adnexal structure measuring 6.5 x 2.5 x 1.5 cm in greatest dimension. The fallopian tube measures 3.5 x 1.5 x 0.9 cm and exhibits a tan convoluted, shiny surface. Arising from one pole of the ovary is an irregular lobulated mass measuring 4 x 2.3 x 2.1 cm in greatest dimension. This mass is covered by a shiny purple-tan membrane and on cut section, reveals solid lobules of tan villiform tissue. The fallopian tube measures 5 cm in length x 0.5 cm in average diameter. Multiple unilocular paratubal cysts, ranging in size from 0.2 cm to 1 cm, are present at the distal end of the tube. The largest cyst exhibits a roughened and wrinkled lining. Tubo-ovarian adhesions are present. Labelled L01, ovary with tumor arising from it; L02, tumor mass; [REDACTED] fallopian tube with largest noted paratubal cyst. [REDACTED]

The third container is additionally labelled "FS1," and contains an irregular yellow glistening fragment of tissue measuring 1 x 0.5 x 0.2 cm. [REDACTED]

The fourth container is additionally labelled "right adnexal tumor mass," and contains a wrinkled, thickened sheet of tissue which measures 14 x 7.5 x 0.5 cm in greatest dimension. One surface is light tan and exhibits cerebroform folds, adherent fibrous strands and focal light tan papillary excrescences. The opposite surface is purple-gray and ragged with adherent bits of fibrofatty tissue. Cut section reveals the sheet of tissue to be composed of layered, shiny white and glistening tan fibroconnective tissue. A focal area is expanded to 1.3 cm in maximal thickness and exhibits lobules of tan, solid villiform tumor. This region measures 2.5 x ~2 cm. Two irregular, rubbery fragments of purple-gray

[page 4 of 4]
[REDACTED] fibroconnective tissue are also received. These measure 3.5 x 1.8 x 0.4 cm and 5 x 2.5 x 1.5 cm. Neither grossly identifiable ovary or fallopian tube is identified. [REDACTED] expanded area with tan villiform tumor; R2 and R3, papillary excrescences. [REDACTED]

The fifth container is additionally labelled "right cul-de-sac biopsy." Three irregular fragments of yellow and tan tissue, which together measure 2.5 x 1.5 x 1 cm in greatest dimension. the tissue is variably white, shiny and rubbery and soft and fatty in nature. Tumor tissue is not clearly identified. Labelled C and D. [REDACTED]

The sixth container is additionally labelled "small bowel proximal," and contains a 7.5 cm in length x 2.5 cm in diameter segment of small bowel with attached mesenteric tissue, measuring 7 x 2 cm. A tan, shiny tumor nodule measuring 1.5 x 1.5 cm in area is present 2 cm from one end of the specimen. The tumor nodule surrounds and invades the bowel wall transmurally. The remaining bowel is unremarkable with the serosa being smooth, tan and shiny and the mucosa being tan, glistening and plicated. The specimen is unoriented. Labelled E, bowel with tumor; F, margin of resection nearest tumor; G, margin of resection farthest from tumor. [REDACTED]

The seventh container is additionally labelled "small bowel," and contains a 19 cm in length x 2 cm in diameter segment of small bowel with attached mesentery, measuring 19 x 2.5 cm. The serosal surface is smooth, shiny and tan and exhibits four tumor nodules arising at the mesenteric aspect of the bowel. These range in size from 1.9 x 2 cm to 1.2 x 0.8 cm. The largest nodule exhibits transmural invasion with ulceration of the small bowel mucosa being identified. The remaining nodules appear to invade maximally to the submucosa. The margins of excision measure 2 cm and 1 cm from tumor mass. The uninvolved bowel exhibits unremarkable tan, glistening, plicated mucosa. Labelled H, tumor nodule with probable transmural invasion; I, resection margin measuring 2 cm from tumor; J, resection margin measuring 1 cm from tumor. [REDACTED]

The eighth container is additionally labelled "mesenteric tumor mass," and contains an irregular shaggy mass of pink-tan tissue measuring 2.5 x 2 x 1 cm. Cut section reveals solid areas of white-tan tumor surrounding central areas of necrosis. Labelled K. Jar 1.

The ninth container is labelled "portion transverse colon" and contains a 15 cm in length x 5 cm in circumference segment of large bowel and attached pericolic fat. At one end, the pericolic fat is firm and roughened and exhibits, what appear to be, blackened cautery marks. This area measures 7 x 4 cm. The bowel wall in this region is thickened and firm. Cut section reveals a poorly defined white-tan tumor mass which replaces the muscularis propria and invades the submucosa. The mucosa overlying this region is largely unremarkable, being red-tan, glistening and folded. However, one focus of ulceration measuring 0.2 cm in diameter is present in the mucosa overlying the described tumor. The described tumor mass appears to extend into the lamina propria underlying the ulcerated region. The described tumor mass appears to extend to within <0.3 cm of one resection margin. It extends to within 7 cm of the opposite resection margin. Further lesions are not apparent. Occasional lymph nodes are found. One lymph node appears grossly involved with tumor. Labelled L, section through apparent mucosal ulceration; M, full thickness sections of bowel with tumor; N, lymph nodes; O, resection margin nearest tumor; P, opposite resection margin. [REDACTED]

The tenth container is additionally labelled "[REDACTED] remnant," and contains three irregular fragments of bowel, ranging in size from 1.5 x 0.3 x 0.3 cm to 4 x 1 x 0.8 cm. One of the fragments exhibit a 0.5 cm in diameter tan, glistening tumor nodule attached to the serosal surface. The other fragments are unremarkable. [REDACTED]

The eleventh container is labelled "umbilicus," and contains a creased, semicircular piece of tan, hairless skin with underlying subcutaneous tissue. The specimen measures 1.6 x 0.9 cm in area x 0.2 cm in depth. No gross lesions are appreciated. Labelled R. [REDACTED]

The twelfth container is labelled "sigmoid serosa tumor tissue," and contains multiple, irregular fragments of tan tissue which

Source: NCI Genomic Data Commons file 217d39ef-e3e2-4e25-926a-176520c567b4 (TCGA-24-2297.12B02227-4050-4D02-BDB8-939D348A4C19.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).